Somatic mutation profile of tumor specimen ER-ADBL-TTM1-A (aliquot ER-ADBL-TTM1-A-2-0-D-A504-35) from EXCEPTIONAL_RESPONDERS case ER-ADBL, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders). Sex at birth: male; Vital status: Alive; Primary diagnosis: Melanoma, NOS; Tissue or organ of origin: Skin of lower limb and hip; AJCC pathologic stage: Stage IIB; Age at diagnosis: 65.7 years (23,981 days).
Specimen ER-ADBL-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9579fc21-f61e-4e9b-9672-4d8ee31da18f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ER-ADBL-NT1-A (Solid Tissue Normal), aliquot ER-ADBL-NT1-A-2-0-D-A504-35; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f231f67-ccb7-4947-b854-1aa376b57860

The open-access MAF lists 31 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 8, Nonsense Mutation 2, 3'UTR 2, In Frame Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 210/660 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CRLF2 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 174/698 reads (25%) | hotspot (GDC flag); SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1319865856, COSV67493811; called by muse, mutect2, varscan2
- BCOR | c.3613C>T p.P1205S (on ENST00000378444 / NM_001123385.2; = p.P1171S on NM_017745.6) | Missense Mutation (SNP) | VAF 271/444 reads (61%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.998); catalogued as COSV60707167; called by muse, mutect2, varscan2
- CDC73 | c.664C>T p.R222* | Nonsense Mutation (SNP) | VAF 354/751 reads (47%) | catalogued as CM032945, COSV66467551, COSV66468296; called by muse, mutect2, varscan2
- EGFR | c.3287C>T p.S1096F | Missense Mutation (SNP) | VAF 159/597 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51794983; called by muse, mutect2, varscan2
- FANCI | c.157+8T>A | Splice Region (SNP) | VAF 150/351 reads (43%) | catalogued as rs1567141408; called by muse, mutect2, varscan2
- FAT3 | c.13322C>T p.S4441F | Missense Mutation (SNP) | VAF 204/461 reads (44%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as COSV53172888; called by muse, mutect2, varscan2
- FGFR1 | c.995C>T p.S332F (on ENST00000447712 / NM_023110.3; = p.S330F on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 233/767 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as CM070126, COSV58327622; called by muse, mutect2, varscan2
- FLT3 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 118/490 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.709); catalogued as COSV54062516; called by muse, mutect2, varscan2
- PLCG2 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 172/409 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as rs1337238313; called by muse, mutect2, varscan2
- PREX2 | c.3274G>A p.D1092N | Missense Mutation (SNP) | VAF 198/615 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99907806; called by muse, varscan2
- PREX2 | c.4210C>T p.H1404Y | Missense Mutation (SNP) | VAF 169/642 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs866534903, COSV55770593; called by muse, mutect2, varscan2
- PTPRD | c.199C>T p.Q67* | Nonsense Mutation (SNP) | VAF 242/504 reads (48%) | catalogued as COSV61937304; called by muse, varscan2
- RUNX1T1 | c.176C>T p.P59L (on ENST00000265814 / NM_001198628.1; = p.P32L on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 189/619 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs552022984, COSV56154509; called by muse, mutect2, varscan2
- SPTA1 | c.2728G>A p.E910K | Missense Mutation (SNP) | VAF 221/874 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598102, COSV100934909, COSV63755764; called by muse, mutect2, varscan2
- ALOX12B | c.1958T>G p.F653C | Missense Mutation (SNP) | VAF 188/595 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CHUK | c.1863_1865dup p.L622dup | In Frame Ins (INS) | VAF 109/323 reads (34%) | called by mutect2, pindel, varscan2
- KEL | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 180/602 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- NCOR1 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 207/725 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- PIK3CB | c.158C>T p.S53F | Missense Mutation (SNP) | VAF 141/315 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- SLIT2 | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 166/607 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CARD11 | c.3225C>T p.F1075= | Silent (SNP) | VAF 205/694 reads (30%) | called by muse, mutect2, varscan2
- FLT3 | c.2406G>A p.L802= | Silent (SNP) | VAF 119/496 reads (24%) | called by muse, mutect2, varscan2
- PAX5 | c.270C>T p.V90= | Silent (SNP) | VAF 167/452 reads (37%) | catalogued as rs371493752, COSV63906039, COSV63909077; called by muse, mutect2, varscan2
- POLD1 | c.978C>T p.F326= | Silent (SNP) | VAF 139/316 reads (44%) | catalogued as COSV70954801; called by muse, mutect2, varscan2
- PREX2 | c.2463C>T p.V821= | Silent (SNP) | VAF 175/566 reads (31%) | catalogued as rs367908867; called by mutect2, varscan2
- PTPRD | c.4194C>T p.L1398= | Silent (SNP) | VAF 237/530 reads (45%) | catalogued as rs757038656; called by muse, mutect2, varscan2
- SLIT2 | c.3777G>A p.G1259= | Silent (SNP) | VAF 190/595 reads (32%) | catalogued as COSV56595389; called by muse, mutect2, varscan2
- TRRAP | c.8430C>T p.S2810= (on ENST00000359863 / NM_001244580.1; = p.S2792= on NM_003496.3) | Silent (SNP) | VAF 149/544 reads (27%) | called by muse, mutect2, varscan2
- BCL2 | c.*4009T>C | 3'UTR (SNP) | VAF 212/661 reads (32%) | called by muse, mutect2, varscan2
- CHEK2 | c.*19G>A | 3'UTR (SNP) | VAF 108/330 reads (33%) | catalogued as rs1057523052; ClinVar: likely benign; called by muse, mutect2, varscan2
